CPTAC case C3L-04084 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0345c668-0597-49a9-80b6-17cc9cc9cae7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1954; Vital status: Dead; Days to death: 274 days; Year of death: 2019; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Parietal lobe; Age at diagnosis: 63.7 years (23,267 days); Year of diagnosis: 2018; Days to last known disease status: 274 days; Days to last follow up: 206 days.
   Pathology details: Greatest tumor dimension: 5.4 cm.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 206.

Other clinical attributes
- Weight: 55.34 kg; Height: 152.4 cm; BMI: 23.82; AIDS risk factors: Encephalopathy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04084-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -2 days; Initial weight: 2,724 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04084-24: Section location: Parietal Lobe; Percent tumor nuclei: 90; Percent necrosis: 5.
- Sample C3L-04084-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -2 days; Method of sample procurement: Blood Draw.
